Somatic mutation profile of tumor specimen HCM-CSHL-0078-C25-01A (aliquot HCM-CSHL-0078-C25-01A-11D-A78M-36) from HCMI case HCM-CSHL-0078-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 72.6 years (26,533 days).
Specimen HCM-CSHL-0078-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce5d9df6-f82a-484f-9685-45c391994afa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0078-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0078-C25-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/378c07f3-0954-4d16-8ddd-14403ba51691

The open-access MAF lists 120 somatic variants for this specimen: 78 protein-altering or splice-affecting, 25 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 25, Frame Shift Del 5, RNA 4, Intron 4, Nonsense Mutation 3, 5'Flank 3, 5'UTR 2, 3'UTR 2, 3'Flank 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>T p.C275F | Missense Mutation (SNP) | VAF 218/470 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADNP | c.3062G>C p.G1021A | Missense Mutation (SNP) | VAF 92/248 reads (37%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as rs1237911024; called by muse, mutect2, varscan2
- BCAS3 | c.1969G>A p.V657I (on ENST00000390652 / NM_001353144.2; = p.V642I on NM_017679.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.44); PolyPhen benign (0.093); catalogued as rs766648044; called by muse, mutect2, varscan2
- C2orf50 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as COSV101059477; called by muse, mutect2, varscan2
- CDC5L | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 81/180 reads (45%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs756396867; called by muse, mutect2, varscan2
- DOK2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 63/397 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs766198984; called by muse, mutect2, varscan2
- FBXO15 | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.3); catalogued as rs202075662, COSV99077190; called by muse, mutect2, varscan2
- GABRD | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.659); catalogued as rs1259972227; called by muse, mutect2, varscan2
- HOXD12 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs1216506512, COSV101184276; called by muse, mutect2, varscan2
- HRNR | c.1640G>A p.R547Q | Missense Mutation (SNP) | VAF 113/1012 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs769962080, COSV64256820; called by muse, mutect2, varscan2
- KLF12 | c.628A>G p.I210V | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs774840041; called by mutect2, varscan2
- LAMA5 | c.778C>A p.R260S | Missense Mutation (SNP) | VAF 167/540 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53362723; called by muse, mutect2, varscan2
- LAMC2 | c.2444G>A p.G815E | Missense Mutation (SNP) | VAF 60/294 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as COSV51456248; called by muse, mutect2, varscan2
- LPA | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 107/535 reads (20%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.98); catalogued as rs1170862921, COSV60303792; called by muse, mutect2, varscan2
- MINDY4 | c.1477C>T p.R493C | Missense Mutation (SNP) | VAF 35/349 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs370104814; called by muse, mutect2, varscan2
- OR4M1 | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 94/340 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV100270969, COSV60060509; called by mutect2, varscan2
- OXNAD1 | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1389018393, COSV53265982; called by muse, mutect2, varscan2
- PALM | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 51/273 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs372771354; called by muse, mutect2, varscan2
- POLR1E | c.1046G>A p.R349Q (on ENST00000377792 / NM_001282766.1; = p.R287Q on NM_022490.4) | Missense Mutation (SNP) | VAF 55/228 reads (24%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.748); catalogued as rs745330508, COSV66773064; called by muse, mutect2, varscan2
- PRAMEF27 | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 98/573 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1174375626; called by muse, mutect2, varscan2
- RGS3 | c.3392C>T p.A1131V (on ENST00000350696 / NM_001282923.2; = p.A850V on NM_130795.4) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs144334750; called by muse, mutect2, varscan2
- SSTR4 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs372339309; called by muse, mutect2, varscan2
- TMEM91 | c.512C>T p.P171L | Missense Mutation (SNP) | VAF 59/237 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.068); catalogued as rs1032654429, COSV99652565; called by muse, mutect2, varscan2
- UACA | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 60/98 reads (61%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778220594; called by mutect2, varscan2
- USP6NL | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs781289702, COSV53209782; called by muse, mutect2, varscan2
- VEPH1 | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 88/236 reads (37%) | catalogued as COSV62882192; called by muse, mutect2, varscan2
- ZFHX4 | c.6683C>T p.S2228F | Missense Mutation (SNP) | VAF 42/247 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV99256741; called by muse, mutect2, varscan2
- ZNF536 | c.2011C>T p.R671W | Missense Mutation (SNP) | VAF 100/223 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1180623012, COSV62818669; called by muse, mutect2, varscan2
- ADGRL3 | c.4396A>G p.S1466G (on ENST00000506720 / NM_001322402.2; = p.S1355G on NM_015236.6) | Missense Mutation (SNP) | VAF 60/201 reads (30%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- AGTPBP1 | c.3619G>T p.E1207* (on ENST00000357081 / NM_001330701.2; = p.E1167* on NM_015239.2) | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- ARFGEF3 | c.2435G>C p.S812T | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNG6 | c.649del p.Y217Tfs*13 (on ENST00000252729 / NM_145814.1; = p.Y146Tfs*13 on NM_031897.2) | Frame Shift Del (DEL) | VAF 12/146 reads (8%) | called by mutect2, pindel
- CDH23 | c.6472G>A p.A2158T | Missense Mutation (SNP) | VAF 223/528 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CEACAM18 | c.968G>C p.C323S | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG3 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- DDX31 | c.1189G>A p.G397S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNASE1L1 | c.662G>A p.S221N | Missense Mutation (SNP) | VAF 96/205 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- DNASE2 | c.141_142del p.G48Afs*49 | Frame Shift Del (DEL) | VAF 56/412 reads (14%) | called by pindel, varscan2
- FAM169A | c.731G>A p.G244D | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- FBXL16 | c.1272G>T p.L424F | Missense Mutation (SNP) | VAF 10/306 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- FLG | c.1599G>T p.E533D | Missense Mutation (SNP) | VAF 92/994 reads (9%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.928); called by muse, mutect2
- FOXC1 | c.18dup p.V7Rfs*76 | Frame Shift Ins (INS) | VAF 22/54 reads (41%) | called by mutect2, pindel, varscan2
- FRMD6 | c.1043A>G p.E348G (on ENST00000344768 / NM_001267046.2; = p.E340G on NM_152330.4) | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GAL3ST1 | c.499G>A p.A167T | Missense Mutation (SNP) | VAF 122/247 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- GPR137C | c.548C>G p.T183S | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.831); called by muse, mutect2
- H4C2 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 15/217 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); called by muse, mutect2
- HECA | c.437A>G p.N146S | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KDM5C | c.1503_1519del p.W501Cfs*10 | Frame Shift Del (DEL) | VAF 45/133 reads (34%) | called by mutect2, pindel, varscan2
- L3MBTL4 | c.659A>G p.D220G | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LPIN2 | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 38/454 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEGF8 | c.6065C>T p.T2022I (on ENST00000251268 / NM_001271938.2; = p.T1955I on NM_001410.3) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.399); called by muse, mutect2
- MROH5 | c.2816G>C p.S939T | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- MUC6 | c.6589_6590del p.L2197Ffs*12 | Frame Shift Del (DEL) | VAF 32/184 reads (17%) | called by pindel, varscan2
- NEB | c.16955A>G p.Y5652C | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR51C1P | c.830C>G p.A277G | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- OTOG | c.7977G>T p.E2659D | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PDE6B | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PHF12 | c.1885C>G p.P629A | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.046); called by muse, mutect2
- PTPN13 | c.7224C>A p.C2408* (on ENST00000411767 / NM_080683.3; = p.C2389* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 50/215 reads (23%) | called by muse, mutect2, varscan2
- RABGAP1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RBCK1 | c.1029+1G>C p.X343_splice (on ENST00000356286 / NM_031229.4; = p.X301_splice on NM_006462.6) | Splice Site (SNP) | VAF 9/243 reads (4%) | called by muse, mutect2
- RBM26 | c.1303C>G p.P435A | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RIOK2 | c.290T>C p.V97A | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- SAMD8 | c.204A>T p.L68F | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- SCN2A | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 74/543 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- SLC5A8 | c.1714_1716del p.K572del | In Frame Del (DEL) | VAF 21/75 reads (28%) | called by pindel, varscan2
- TANC1 | c.3821C>T p.A1274V | Missense Mutation (SNP) | VAF 116/295 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- TEX44 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 26/660 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TMEM121 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMEM237 | c.874G>T p.D292Y (on ENST00000409883 / NM_001044385.3; = p.D284Y on NM_152388.4) | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNKS | c.160G>T p.A54S | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TTN | c.31510C>G p.P10504A (on ENST00000591111; = p.P9577A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/208 reads (12%) | PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- URB1 | c.4720C>G p.H1574D | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- WDR62 | c.77del p.P26Rfs*51 | Frame Shift Del (DEL) | VAF 48/254 reads (19%) | called by mutect2, pindel, varscan2
- WNK2 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 277/684 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- YWHAE | c.265-1G>C p.X89_splice | Splice Site (SNP) | VAF 8/78 reads (10%) | called by mutect2, varscan2
- ZFHX2 | c.6059G>C p.S2020T | Missense Mutation (SNP) | VAF 35/245 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF202 | c.1534A>C p.T512P | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.472); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1377C>T p.P459= | Silent (SNP) | VAF 109/1964 reads (6%) | catalogued as rs779949072, COSV55000365; called by muse, mutect2
- ATG4B | c.222C>T p.C74= | Silent (SNP) | VAF 54/421 reads (13%) | called by muse, mutect2, varscan2
- CLSTN2 | c.696G>T p.L232= | Silent (SNP) | VAF 97/227 reads (43%) | called by muse, mutect2, varscan2
- DPF2 | c.432C>T p.G144= | Silent (SNP) | VAF 48/194 reads (25%) | catalogued as COSV52888870; called by muse, mutect2, varscan2
- ELOA2 | c.1182G>A p.K394= | Silent (SNP) | VAF 67/338 reads (20%) | called by muse, mutect2, varscan2
- EVC2 | c.3615C>T p.S1205= | Silent (SNP) | VAF 121/487 reads (25%) | called by muse, mutect2, varscan2
- FLG | c.7242C>T p.F2414= | Silent (SNP) | VAF 96/1043 reads (9%) | called by muse, mutect2
- GNAT1 | c.435C>T p.N145= | Silent (SNP) | VAF 24/366 reads (7%) | catalogued as rs749785058; called by muse, mutect2
- IRX3 | c.1473C>T p.A491= | Silent (SNP) | VAF 105/275 reads (38%) | called by muse, mutect2, varscan2
- ITIH3 | c.729C>G p.L243= | Silent (SNP) | VAF 23/449 reads (5%) | catalogued as COSV101406950; called by muse, mutect2
- MED23 | c.1296C>A p.L432= | Silent (SNP) | VAF 55/325 reads (17%) | called by muse, mutect2, varscan2
- NEB | c.10305G>A p.P3435= | Silent (SNP) | VAF 64/433 reads (15%) | catalogued as rs528974814, COSV99415147; ClinVar: likely benign; called by muse, mutect2, varscan2
- NEXMIF | c.1749C>T p.P583= | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- NPC1L1 | c.927C>T p.P309= | Silent (SNP) | VAF 16/126 reads (13%) | catalogued as rs1017546573, COSV56922987; called by muse, mutect2, varscan2
- OBSCN | c.5016G>A p.V1672= | Silent (SNP) | VAF 90/403 reads (22%) | catalogued as COSV99486630; called by muse, mutect2, varscan2
- OR13C2 | c.630T>G p.P210= | Silent (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- PGM5 | c.1566C>T p.Y522= | Silent (SNP) | VAF 48/264 reads (18%) | catalogued as rs782534536, COSV67166795; called by muse, mutect2, varscan2
- RBM25 | c.462G>A p.E154= | Silent (SNP) | VAF 35/214 reads (16%) | called by muse, mutect2, varscan2
- SPATA31E1 | c.1080C>T p.D360= | Silent (SNP) | VAF 58/416 reads (14%) | catalogued as rs199568188, COSV57789870; called by muse, mutect2, varscan2
- TIE1 | c.2826T>C p.A942= | Silent (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- TNRC18 | c.5952G>A p.A1984= | Silent (SNP) | VAF 51/331 reads (15%) | catalogued as rs778246311; called by muse, mutect2, varscan2
- TSPAN5 | c.606T>C p.Y202= | Silent (SNP) | VAF 36/215 reads (17%) | catalogued as rs760214816; called by muse, mutect2, varscan2
- URB2 | c.1920G>A p.E640= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- VPS13D | c.4890G>A p.Q1630= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- ZNF556 | c.15C>A p.V5= | Silent (SNP) | VAF 61/240 reads (25%) | called by muse, mutect2, varscan2
- AC006305.1 | n.825A>G | RNA (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- ACBD4 | chr17:45143641 G>A | 3'Flank (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- BTN2A3P | n.1585C>T | RNA (SNP) | VAF 22/803 reads (3%) | called by muse, mutect2
- DSTN | c.-84G>T | 5'UTR (SNP) | VAF 49/253 reads (19%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+325T>C | Intron (SNP) | VAF 79/429 reads (18%) | called by muse, mutect2, varscan2
- FAM161A | c.*1279T>C | 3'UTR (SNP) | VAF 15/75 reads (20%) | called by muse, mutect2, varscan2
- GPNMB | c.541+30C>A | Intron (SNP) | VAF 104/311 reads (33%) | called by muse, mutect2, varscan2
- HADH | chr4:107989882 C>G | 5'Flank (SNP) | VAF 53/227 reads (23%) | catalogued as rs536959577, COSV100531279, COSV58848862; called by muse, mutect2, varscan2
- HAUS7 | chrX:153470957 T>A | 5'Flank (SNP) | VAF 44/105 reads (42%) | called by muse, mutect2, varscan2
- LINC00602 | n.592C>A | RNA (SNP) | VAF 85/363 reads (23%) | catalogued as rs969920362; called by muse, mutect2, varscan2
- LINC01193 | n.1330C>A | RNA (SNP) | VAF 29/431 reads (7%) | called by muse, mutect2
- NDUFA4 | c.43-20C>T | Intron (SNP) | VAF 11/188 reads (6%) | called by muse, mutect2
- PADI4 | c.-2C>T | 5'UTR (SNP) | VAF 49/164 reads (30%) | catalogued as rs200461292; called by muse, mutect2, varscan2
- PYCARD | c.275-76del | Intron (DEL) | VAF 32/172 reads (19%) | called by mutect2, pindel, varscan2
- RNU7-174P | chr8:80559425 C>T | 5'Flank (SNP) | VAF 83/515 reads (16%) | catalogued as rs1159050845; called by muse, mutect2, varscan2
- VMP1 | c.*1440C>A | 3'UTR (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2, varscan2
- WASHC3 | chr12:102011836 G>A | 3'Flank (SNP) | VAF 41/216 reads (19%) | catalogued as rs1212203202; called by muse, mutect2, varscan2
